Somatic mutation profile of tumor specimen TCGA-A4-7287-01A (aliquot TCGA-A4-7287-01A-11D-2136-08) from TCGA case TCGA-A4-7287, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 75.6 years (27,621 days).
Specimen TCGA-A4-7287-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 530163c6-58d4-42a9-8b9a-e01daf192132.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-7287-10A (Blood Derived Normal), aliquot TCGA-A4-7287-10A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7522176-7c63-4e27-93a3-5f51157de8fe

The open-access MAF lists 44 somatic variants for this specimen: 31 protein-altering or splice-affecting, 10 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 10, Splice Site 2, 5'UTR 1, Frame Shift Ins 1, RNA 1, Frame Shift Del 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AOC2 | c.844G>C p.V282L | Missense Mutation (SNP) | VAF 19/94 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV53200199; called by muse, mutect2, varscan2
- CCDC85A | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as rs766959547, COSV101339460, COSV68154975; called by muse, mutect2
- CDC73 | c.272G>A p.R91Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM072926, COSV66465222; called by muse, mutect2, varscan2
- COASY | c.1303-1G>T p.X435_splice | Splice Site (SNP) | VAF 38/199 reads (19%) | catalogued as COSV55900223; called by muse, mutect2, varscan2
- COL9A1 | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.271); catalogued as rs1159414513, COSV57891772; called by muse, mutect2, varscan2
- CRISP3 | c.799G>A p.A267T (on ENST00000371159 / NM_001368123.1; = p.A249T on NM_006061.4) | Missense Mutation (SNP) | VAF 36/112 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); catalogued as rs1253132642, COSV53821730; called by muse, mutect2, varscan2
- DCK | c.685C>A p.Q229K | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV54379639; called by muse, mutect2, varscan2
- DGCR2 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1456744267, COSV54221247; called by muse, mutect2, varscan2
- FAT4 | c.9409G>A p.G3137S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.06); PolyPhen benign (0.044); catalogued as COSV58704482; called by muse, mutect2, varscan2
- FBXW9 | c.1165C>T p.H389Y (on ENST00000587955; = p.H369Y on NM_032301.3) | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as COSV66710439; called by muse, mutect2, varscan2
- HELZ2 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.054); catalogued as COSV64410385; called by muse, mutect2, varscan2
- HYAL1 | c.24C>G p.I8M | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.293); catalogued as COSV56499237; called by muse, mutect2, varscan2
- IMPG1 | c.1638C>G p.F546L | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.51); PolyPhen benign (0.031); catalogued as COSV100886314, COSV64057375, COSV64061047; called by muse, varscan2
- LBR | c.1143T>A p.F381L | Missense Mutation (SNP) | VAF 25/132 reads (19%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.524); catalogued as COSV55291277; called by muse, mutect2, varscan2
- MSN | c.91G>C p.D31H | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as COSV64305305; called by muse, mutect2, varscan2
- MSRA | c.77C>T p.S26L | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as rs769720226, COSV57809916; called by muse, varscan2
- OGT | c.2012C>T p.A671V | Missense Mutation (SNP) | VAF 29/121 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs946602606, COSV65481915; called by muse, mutect2, varscan2
- OR10Q1 | c.123G>A p.M41I | Missense Mutation (SNP) | VAF 27/101 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0.118); catalogued as COSV57471788; called by muse, mutect2, varscan2
- PCDHA6 | c.2059G>A p.A687T | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.001); catalogued as COSV65342635; called by muse, mutect2
- PLA2G2D | c.326G>A p.C109Y | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs765219229, COSV64282077; called by muse, mutect2, varscan2
- PLEKHG7 | c.284C>G p.S95C | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV67338166; called by muse, mutect2, varscan2
- PRPF6 | c.1518G>C p.W506C | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV53877440; called by muse, mutect2
- RGS21 | c.158C>A p.A53D | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV69883701; called by muse, mutect2, varscan2
- SNRPE | c.125G>A p.R42Q | Missense Mutation (SNP) | VAF 76/224 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV65843411; called by muse, mutect2, varscan2
- STAG2 | c.1958C>A p.S653* | Nonsense Mutation (SNP) | VAF 14/59 reads (24%) | catalogued as COSV54350739, COSV54370552; called by muse, mutect2, varscan2
- TYMS | c.376A>G p.R126G | Missense Mutation (SNP) | VAF 63/393 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.633); catalogued as COSV60075995; called by muse, mutect2, varscan2
- ZKSCAN8 | c.7G>A p.E3K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as COSV57639989; called by muse, mutect2, varscan2
- ZNF189 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT tolerated (0.41); PolyPhen benign (0.011); catalogued as COSV52276689; called by muse, mutect2, varscan2
- LYPD3 | c.522_528del p.D174Efs*4 | Frame Shift Del (DEL) | VAF 22/101 reads (22%) | called by mutect2, pindel, varscan2
- RAB11FIP1 | c.1731dup p.S578Lfs*2 | Frame Shift Ins (INS) | VAF 24/74 reads (32%) | called by mutect2, pindel, varscan2
- TSC1 | c.664-3_665del p.X222_splice | Splice Site (DEL) | VAF 8/26 reads (31%) | called by mutect2, pindel, varscan2
- FTCD | c.597C>A p.I199= | Silent (SNP) | VAF 22/88 reads (25%) | catalogued as COSV52429183; called by muse, mutect2, varscan2
- IMPG1 | c.1467C>T p.I489= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as COSV64055165; called by muse, mutect2, varscan2
- LAMA4 | c.3564C>G p.L1188= (on ENST00000230538 / NM_001105206.3; = p.L1181= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 27/109 reads (25%) | catalogued as COSV57891732, COSV57903650; called by muse, mutect2, varscan2
- MAPT | c.2409C>G p.V803= (on ENST00000262410 / NM_001377265.1; = p.V411= on NM_005910.5) | Silent (SNP) | VAF 10/152 reads (7%) | catalogued as COSV52246480; called by muse, mutect2
- MSRA | c.36C>T p.L12= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV57809905; called by muse, varscan2
- NTRK1 | c.987C>T p.F329= | Silent (SNP) | VAF 7/23 reads (30%) | catalogued as COSV62328184; called by muse, mutect2, varscan2
- SERPINI2 | c.924C>T p.T308= | Silent (SNP) | VAF 16/42 reads (38%) | catalogued as rs140665807; called by muse, mutect2, varscan2
- SIRPG | c.1014G>T p.A338= | Silent (SNP) | VAF 22/81 reads (27%) | catalogued as rs147655438, COSV53809882; called by muse, mutect2, varscan2
- SNRPE | c.126G>A p.R42= | Silent (SNP) | VAF 77/226 reads (34%) | catalogued as COSV65843414; called by muse, mutect2, varscan2
- ZNF385A | c.825A>G p.Q275= (on ENST00000338010 / NM_001130967.3; = p.Q255= on NM_015481.3) | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as rs755528076, COSV61494303; called by muse, mutect2, varscan2
- ATP7A | c.-21-8936A>T | Intron (SNP) | VAF 11/49 reads (22%) | catalogued as COSV100431703; called by muse, mutect2, varscan2
- FAM74A3 | n.268G>C | RNA (SNP) | VAF 6/49 reads (12%) | called by muse, mutect2, varscan2
- GORAB | c.-41C>T | 5'UTR (SNP) | VAF 15/90 reads (17%) | catalogued as rs757102852, COSV63026774; called by muse, mutect2, varscan2
